Somatic mutation profile of tumor specimen ALCH-AFFN-TTP1-A (aliquot ALCH-AFFN-TTP1-A-4-0-D-A657-36) from ALCHEMIST case ALCH-AFFN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,227 days).
Specimen ALCH-AFFN-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74ca9b3f-847f-4e8d-8fde-572ac84dceb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFFN-NB1-A (Blood Derived Normal), aliquot ALCH-AFFN-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73ab7222-f97a-4add-87b6-55d0383b4ad1

The open-access MAF lists 589 somatic variants for this specimen: 396 protein-altering or splice-affecting, 113 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 331, Silent 113, Intron 40, Nonsense Mutation 27, Frame Shift Del 15, RNA 15, Splice Site 14, 3'UTR 12, 5'UTR 7, Splice Region 5, 5'Flank 4, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.4732C>T p.Q1578* | Nonsense Mutation (SNP) | VAF 88/158 reads (56%) | catalogued as rs746499337, CM031640; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 183/386 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.481A>T p.I161F | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs1131690938, CM134908, COSV58828738; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 134/270 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAD10 | c.1781G>T p.W594L | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV58155870; called by muse, mutect2, varscan2
- ADAD2 | c.1395C>A p.H465Q (on ENST00000315906 / NM_001145400.2; = p.H547Q on NM_139174.4) | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs770888310; called by muse, mutect2, varscan2
- ADAMTS14 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs202183313; called by muse, mutect2, varscan2
- ADGRF4 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.381); catalogued as rs112563187, COSV51954824; called by muse, varscan2
- ADNP | c.2570A>G p.N857S | Missense Mutation (SNP) | VAF 105/237 reads (44%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs755878700; called by muse, mutect2, varscan2
- AKAP11 | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs1336218960; called by muse, mutect2, varscan2
- ALDH1L1 | c.1282G>T p.G428W | Missense Mutation (SNP) | VAF 97/268 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56417221; called by muse, mutect2, varscan2
- ALPK3 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1386803579; called by muse, mutect2, varscan2
- ANKRD30B | c.2615C>G p.S872* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV100271265; called by muse, mutect2, varscan2
- APBA2 | c.654C>A p.D218E | Missense Mutation (SNP) | VAF 83/288 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV68793058; called by muse, mutect2, varscan2
- AQP10 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs538916652, COSV100270369; called by muse, mutect2
- ATP1A3 | c.1600G>T p.D534Y (on ENST00000545399 / NM_001256214.2; = p.D521Y on NM_152296.5) | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57491181; called by muse, mutect2
- ATP6V1G3 | c.17A>T p.Q6L | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55280162; called by muse, mutect2, varscan2
- BAZ2A | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.831); catalogued as rs1232130766; called by muse, mutect2, varscan2
- BCL11B | c.2679G>T p.R893S (on ENST00000357195 / NM_001282237.2; = p.R822S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs1463130411, COSV61737631; called by muse, mutect2, varscan2
- BCO1 | c.324-6C>A | Splice Region (SNP) | VAF 96/388 reads (25%) | catalogued as rs762183136; called by mutect2, varscan2
- BNC2 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 95/392 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66157419; called by muse, mutect2, varscan2
- C1orf158 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs575252370, COSV55348053; called by muse, mutect2, varscan2
- CACNA1E | c.217G>T p.G73* | Nonsense Mutation (SNP) | VAF 42/151 reads (28%) | catalogued as COSV62393907; called by muse, mutect2, varscan2
- CACNA1E | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV62382290, COSV62414513; called by muse, mutect2, varscan2
- CATSPER1 | c.2317-1G>T p.X773_splice | Splice Site (SNP) | VAF 54/105 reads (51%) | catalogued as COSV56409335; called by muse, mutect2, varscan2
- CCDC82 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 126/697 reads (18%) | catalogued as rs758691852; called by muse, mutect2, varscan2
- CDC14B | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1447135175; called by muse, mutect2, varscan2
- CDC37 | c.1067A>G p.E356G | Missense Mutation (SNP) | VAF 103/203 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs757312172; called by muse, mutect2, varscan2
- CDH8 | c.1978G>T p.V660F | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as rs1229937786, COSV100184199, COSV54848492; called by muse, mutect2, varscan2
- CDH9 | c.2121G>T p.W707C | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); catalogued as COSV99152176; called by muse, mutect2, varscan2
- CEP295NL | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.322); catalogued as COSV53163504; called by muse, mutect2, varscan2
- CFH | c.2438C>A p.P813H | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100809550; called by muse, mutect2, varscan2
- CFP | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 100/163 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as CM1513404, COSV55949624; called by muse, mutect2, varscan2
- CMKLR1 | c.267C>A p.N89K (on ENST00000312143 / NM_001142344.2; = p.N87K on NM_004072.3) | Missense Mutation (SNP) | VAF 158/373 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100379629; called by muse, mutect2, varscan2
- COL24A1 | c.932G>T p.R311I | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as COSV65301575; called by muse, mutect2, varscan2
- COL4A2 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as rs750061237, COSV64635334; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL5A2 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 42/291 reads (14%) | catalogued as COSV66407372; called by muse, mutect2, varscan2
- COL6A2 | c.928-2A>T p.X310_splice | Splice Site (SNP) | VAF 107/266 reads (40%) | catalogued as COSV56017612; called by muse, mutect2, varscan2
- CPNE7 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs377682585; called by muse, mutect2, varscan2
- CRNKL1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs544729800; called by muse, mutect2, varscan2
- CYP2E1 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.431); catalogued as COSV53312897, COSV53314806; called by muse, mutect2, varscan2
- DDX11 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 50/354 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1565839758; called by muse, varscan2
- DNASE2B | c.561G>T p.L187F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs1333109031; called by muse, varscan2
- DTHD1 | c.2217C>A p.D739E (on ENST00000456874; = p.D574E on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV62630330; called by muse, mutect2, varscan2
- DUOX2 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as rs889965016; called by muse, mutect2, varscan2
- ELAVL4 | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV100836650; called by muse, mutect2, varscan2
- FAM184A | c.794C>G p.T265S | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1410678597; called by muse, mutect2
- FAT1 | c.4723G>T p.A1575S | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as CM152618, COSV71673218, COSV71675307; called by muse, mutect2, varscan2
- FAT3 | c.13087G>T p.A4363S | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs1292661793; called by muse, mutect2, varscan2
- FBN2 | c.5478C>A p.N1826K | Missense Mutation (SNP) | VAF 110/367 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV52522410; called by muse, varscan2
- FGF10 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 108/545 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99240968; called by muse, mutect2, varscan2
- FLT4 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 68/255 reads (27%) | catalogued as COSV56106690, COSV99987884; called by muse, mutect2, varscan2
- GABBR1 | c.1018del p.R340Afs*15 | Frame Shift Del (DEL) | VAF 73/268 reads (27%) | catalogued as COSV63542745; called by mutect2, pindel, varscan2
- GDA | c.578G>T p.R193I | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.561); catalogued as COSV52996301; called by muse, mutect2, varscan2
- GPATCH1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV50118222; called by muse, mutect2, varscan2
- GPR161 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371919925; called by muse, mutect2, varscan2
- GRAMD1C | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV63983047; called by muse, mutect2, varscan2
- GRIN2A | c.2745G>T p.M915I | Missense Mutation (SNP) | VAF 141/481 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100411396; called by muse, mutect2, varscan2
- HECW1 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 132/386 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV67831339; called by muse, mutect2, varscan2
- HHIPL2 | c.801G>T p.W267C | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100596899; called by muse, mutect2, varscan2
- HYDIN | c.1436A>G p.H479R | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs771245870; called by muse, mutect2, varscan2
- IGHV1-2 | c.70G>C p.V24L | Missense Mutation (SNP) | VAF 113/351 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs561566963; called by muse, mutect2, varscan2
- INHBA | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs377167564, COSV54221218; called by muse, mutect2, varscan2
- INPP4B | c.2388T>A p.F796L | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as rs1212144234; called by muse, mutect2, varscan2
- INSC | c.436C>A p.R146S | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101088613; called by muse, mutect2, varscan2
- KCNK10 | c.1066C>G p.R356G | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56641587; called by muse, mutect2, varscan2
- KCNK10 | c.797C>A p.S266Y | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56644969; called by muse, mutect2, varscan2
- KRTAP21-2 | c.204T>A p.C68* | Nonsense Mutation (SNP) | VAF 48/145 reads (33%) | catalogued as COSV100441184; called by muse, mutect2, varscan2
- LAMC3 | c.3266C>A p.A1089D | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as rs971434768; called by muse, mutect2, varscan2
- LILRA4 | c.1447A>G p.S483G | Missense Mutation (SNP) | VAF 12/259 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.916); catalogued as COSV99393475; called by muse, mutect2
- LRIT1 | c.31T>A p.L11M | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV63895459; called by muse, mutect2, varscan2
- LRP2 | c.2486G>T p.R829L | Missense Mutation (SNP) | VAF 44/389 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs376071269; called by muse, mutect2, varscan2
- LRP3 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs376867167; called by muse, mutect2, varscan2
- MARCHF10 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.146); catalogued as COSV60885072; called by muse, mutect2, varscan2
- MDH1B | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs903737992; called by muse, mutect2, varscan2
- MECOM | c.1983G>T p.R661S (on ENST00000468789 / NM_001105078.4; = p.R849S on NM_004991.4) | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV52965742; called by muse, varscan2
- MEDAG | c.364C>G p.Q122E | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV66850389; called by muse, varscan2
- MIB1 | c.1807G>T p.A603S | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as COSV55088692; called by muse, mutect2, varscan2
- MUC17 | c.4204C>A p.P1402T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1483984900; called by muse, mutect2, varscan2
- MUC4 | c.5111C>A p.S1704* | Nonsense Mutation (SNP) | VAF 158/826 reads (19%) | catalogued as COSV100641000; called by muse, varscan2
- MYH1 | c.4034A>T p.D1345V | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56843584; called by muse, mutect2, varscan2
- MYH1 | c.4033G>T p.D1345Y | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56853235; called by muse, mutect2, varscan2
- MYH1 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 96/182 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as rs962798304, COSV56855342; called by muse, mutect2, varscan2
- MYO16 | c.603G>T p.M201I | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99051889; called by muse, mutect2, varscan2
- MYO16 | c.5285G>T p.R1762L | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.199); catalogued as COSV62748351, COSV62764975; called by muse, varscan2
- MYO3A | c.3847A>G p.K1283E | Missense Mutation (SNP) | VAF 160/292 reads (55%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV56351461; called by muse, mutect2, varscan2
- NEFM | c.1978C>A p.P660T | Missense Mutation (SNP) | VAF 148/442 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99646887; called by muse, varscan2
- NLRP4 | c.1659A>G p.I553M | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs1175234015; called by muse, mutect2, varscan2
- NRDC | c.1803G>T p.Q601H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100703394, COSV61409456; called by muse, mutect2, varscan2
- OR13C9 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 138/346 reads (40%) | catalogued as COSV52241151; called by muse, mutect2, varscan2
- OR2AG2 | c.48del p.I17Ffs*2 | Frame Shift Del (DEL) | VAF 18/123 reads (15%) | catalogued as COSV58454652; called by mutect2, pindel, varscan2
- OR2B11 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); catalogued as COSV100276800, COSV59510350; called by muse, mutect2, varscan2
- OR2T33 | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 76/386 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99040637; called by muse, varscan2
- OR3A1 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 236/406 reads (58%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.516); catalogued as rs1350526054; called by muse, mutect2, varscan2
- OR4A5 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1212854120, COSV60522306; called by muse, mutect2
- OR52E8 | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1180567211, COSV66208366; called by muse, mutect2, varscan2
- OR8H3 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV100539118; called by muse, mutect2
- PALB2 | c.3113G>T p.W1038L | Missense Mutation (SNP) | VAF 80/292 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM070242, COSV55170329; called by muse, mutect2, varscan2
- PCDHA11 | c.2020G>T p.A674S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV100246812; called by muse, mutect2, varscan2
- PLCE1 | c.5396C>T p.P1799L | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as rs1158131470, COSV53361962; called by muse, mutect2
- PNMA8A | c.279G>C p.W93C | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1220480602; called by muse, mutect2
- POLE | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs997586826; ClinVar: uncertain significance; called by muse, mutect2
- POTEI | c.2518C>A p.L840M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs770728491; called by mutect2, varscan2
- POTEM | c.261C>G p.D87E | Missense Mutation (SNP) | VAF 149/1036 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs775462673, COSV69152257; called by muse, varscan2
- PPP4R3B | c.2113G>C p.D705H (on ENST00000616407 / NM_001122964.3; = p.D620H on NM_020463.4) | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as rs1374224580; called by muse, mutect2, varscan2
- PTGS1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99792980; called by muse, varscan2
- RASA3 | c.146G>T p.R49M | Missense Mutation (SNP) | VAF 91/244 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61873692; called by muse, mutect2, varscan2
- RBMS3 | c.676G>T p.G226* | Nonsense Mutation (SNP) | VAF 33/212 reads (16%) | catalogued as COSV99821035; called by muse, mutect2, varscan2
- RELN | c.10107del p.T3370Pfs*29 | Frame Shift Del (DEL) | VAF 84/442 reads (19%) | catalogued as COSV58987921; called by mutect2, pindel, varscan2
- RESF1 | c.3904G>A p.V1302I | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as rs776840536; called by muse, varscan2
- ROBO1 | c.3650C>T p.P1217L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV71395413; called by muse, varscan2
- RPRD1A | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100441862; called by muse, mutect2, varscan2
- RUNX1T1 | c.1501G>T p.A501S (on ENST00000265814 / NM_001198628.1; = p.A474S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/134 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV56137869, COSV56160251; called by muse, mutect2, varscan2
- SAMSN1 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs576497710; called by muse, varscan2
- SBNO1 | c.3052G>T p.A1018S (on ENST00000420886; = p.A1017S on NM_018183.5) | Missense Mutation (SNP) | VAF 90/190 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57341137; called by muse, mutect2, varscan2
- SIX1 | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as rs368974927, CM111904, COSV55959691, COSV55960045; ClinVar: benign; called by muse, mutect2, varscan2
- SLC4A11 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 106/384 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.077); catalogued as COSV101195948; called by muse, mutect2, varscan2
- SMCHD1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1450657748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPINT3 | c.76+1G>T p.X26_splice | Splice Site (SNP) | VAF 37/317 reads (12%) | catalogued as rs749822396; called by muse, mutect2, varscan2
- STK24 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV64823819; called by muse, mutect2, varscan2
- TAAR5 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs763077527; called by muse, mutect2, varscan2
- TADA2A | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 56/451 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs761169873; called by muse, mutect2, varscan2
- TCF24 | c.201C>A p.H67Q | Missense Mutation (SNP) | VAF 76/113 reads (67%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.87); catalogued as COSV72955269; called by muse, mutect2, varscan2
- TINAG | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs115438249, COSV52508165; called by muse, mutect2, varscan2
- TLL1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV50349821; called by muse, mutect2, varscan2
- TLR4 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV62922407; called by muse, mutect2, varscan2
- TMCO5A | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60464908; called by muse, mutect2, varscan2
- TMEM14B | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs1425041216, COSV101077458; called by muse, mutect2, varscan2
- TMEM178B | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 54/314 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs572778443; called by muse, mutect2, varscan2
- TRIOBP | c.1172C>A p.S391Y | Missense Mutation (SNP) | VAF 122/458 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV100731051; called by muse, mutect2, varscan2
- TSPYL6 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100336298; called by muse, mutect2, varscan2
- TTBK1 | c.1296C>A p.S432R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.986); catalogued as rs1303774027, COSV52488780; called by muse, mutect2, varscan2
- TYRO3 | c.2325G>T p.Q775H | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.764); catalogued as COSV99777614; called by muse, mutect2, varscan2
- UBA6 | c.2075G>A p.R692K | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV59176030; called by muse, mutect2, varscan2
- UBE2J2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as rs1268175928, COSV59574004; called by muse, mutect2, varscan2
- UMOD | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs747592262; called by muse, mutect2
- USP29 | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV54140424; called by muse, mutect2
- VPS41 | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV56069039, COSV99731113; called by muse, mutect2, varscan2
- ZC3H3 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 85/149 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); catalogued as rs763233967; called by muse, mutect2, varscan2
- ZIM2 | c.1482C>G p.Y494* | Nonsense Mutation (SNP) | VAF 34/280 reads (12%) | catalogued as COSV99690316; called by muse, mutect2, varscan2
- ZNF730 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101659640; called by muse, mutect2, varscan2
- ZNF98 | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs776189787; called by muse, mutect2, varscan2
- A2ML1 | c.2897T>A p.M966K | Missense Mutation (SNP) | VAF 69/118 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCA13 | c.4503G>T p.R1501S | Missense Mutation (SNP) | VAF 63/223 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, varscan2
- ABCA3 | c.1514A>C p.E505A | Missense Mutation (SNP) | VAF 101/431 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.071); called by mutect2, varscan2
- ABCC9 | c.3814C>A p.L1272M | Missense Mutation (SNP) | VAF 52/408 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- AC006059.2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- ADAM19 | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTS12 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS6 | c.3281T>A p.L1094Q | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRA1 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- AKAP6 | c.3728A>T p.Q1243L | Missense Mutation (SNP) | VAF 72/446 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AKTIP | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- AMMECR1L | c.726C>T p.D242= | Splice Region (SNP) | VAF 34/200 reads (17%) | called by muse, mutect2, varscan2
- ANK2 | c.4321G>T p.V1441L | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.187); called by muse, varscan2
- ANKRD16 | c.296G>T p.C99F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); called by muse, varscan2
- ANKRD20A1 | c.2830dup p.A944Gfs*15 | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.4185A>T p.E1395D (on ENST00000611781; = p.E1339D on NM_052997.2) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ANXA13 | c.70A>T p.N24Y | Missense Mutation (SNP) | VAF 68/504 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARFGEF1 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 195/302 reads (65%) | SIFT tolerated (0.56); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ARHGAP21 | c.2494A>T p.T832S | Missense Mutation (SNP) | VAF 119/242 reads (49%) | SIFT tolerated (0.82); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARHGEF1 | c.2413G>T p.E805* | Nonsense Mutation (SNP) | VAF 31/220 reads (14%) | called by muse, mutect2, varscan2
- AS3MT | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASPM | c.2141A>T p.D714V | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BBX | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- C10orf71 | c.4115C>A p.A1372D | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C10orf88 | c.1182G>T p.M394I | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- C4orf54 | c.4580C>A p.T1527N | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- CARMIL3 | c.4046C>A p.S1349Y | Missense Mutation (SNP) | VAF 93/253 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CASZ1 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- CBLC | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- CBX2 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CCDC51 | c.53A>G p.H18R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2
- CDC14A | c.1147_1148dup p.D384Kfs*7 | Frame Shift Ins (INS) | VAF 44/168 reads (26%) | called by pindel, varscan2
- CDH10 | c.535G>T p.V179L | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CDIN1 | c.390G>C p.Q130H (on ENST00000437989; = p.Q32H on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- CENPT | c.31_35del p.T11Afs*32 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- CHODL | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CLMP | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.324); called by muse, mutect2
- COL11A2 | c.3452C>A p.P1151H (on ENST00000341947 / NM_080680.3; = p.P1044H on NM_080679.2) | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- COL15A1 | c.3272G>T p.R1091I | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- COL6A3 | c.9263G>T p.R3088M | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- COL6A5 | c.4479+2T>G p.X1493_splice | Splice Site (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- CORO2B | c.871-1G>T p.X291_splice | Splice Site (SNP) | VAF 88/372 reads (24%) | called by muse, varscan2
- CPLANE2 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CRAMP1 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CRAMP1 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSF2RA | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 158/320 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, varscan2
- CSMD2 | c.7052G>T p.C2351F | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.3116G>T p.G1039V (on ENST00000297405 / NM_001363185.1; = p.G935V on NM_052900.3) | Missense Mutation (SNP) | VAF 229/460 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- CUBN | c.10032+1G>T p.X3344_splice | Splice Site (SNP) | VAF 138/278 reads (50%) | called by muse, mutect2, varscan2
- CUBN | c.7912+1G>T p.X2638_splice | Splice Site (SNP) | VAF 18/584 reads (3%) | called by muse, mutect2
- CUL4A | c.2150C>T p.S717F (on ENST00000375440 / NM_001008895.4; = p.S617F on NM_003589.3) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- DACH1 | c.533C>A p.P178Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- DBX1 | c.682T>G p.W228G | Missense Mutation (SNP) | VAF 64/342 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCTN1 | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 36/528 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2
- DDX18 | c.1540G>T p.G514C | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.7426C>T p.Q2476* (on ENST00000445597; = p.Q3129* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 46/230 reads (20%) | called by muse, mutect2, varscan2
- DNAH3 | c.10740C>A p.N3580K | Missense Mutation (SNP) | VAF 88/343 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- DOCK10 | c.5932G>T p.V1978F | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DST | c.10156C>A p.Q3386K | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DTNA | c.1634A>T p.Q545L | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DZIP1L | c.849del p.K283Nfs*6 | Frame Shift Del (DEL) | VAF 30/76 reads (39%) | called by mutect2, pindel*, varscan2
- EPHA4 | c.2506G>T p.A836S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA5 | c.1074del p.S359Lfs*63 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- EPOP | c.896A>T p.Q299L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ERC2 | c.2402A>T p.Q801L | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- EREG | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ESPL1 | c.2716C>A p.Q906K | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2
- EVC | c.726G>T p.M242I | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- EXD3 | c.2574C>G p.S858R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- EYA4 | c.321A>T p.E107D | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2
- F5 | c.2077T>C p.Y693H | Missense Mutation (SNP) | VAF 125/400 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- FAM189A1 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FAM47A | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- FOXO1 | c.1335_1340delinsAT p.N445Kfs*2 | Frame Shift Del (DEL) | VAF 57/442 reads (13%) | called by pindel, varscan2*
- FREM3 | c.3671C>A p.P1224Q | Missense Mutation (SNP) | VAF 65/214 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRY | c.1488_1492del p.N496Kfs*10 | Frame Shift Del (DEL) | VAF 34/205 reads (17%) | called by mutect2, pindel, varscan2
- FSIP2 | c.11813C>A p.S3938Y | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- FURIN | c.993G>C p.E331D | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FUT6 | c.374G>T p.R125M | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAPDHS | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDF10 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); called by muse, mutect2
- GIMAP8 | c.355C>A p.Q119K | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNRHR | c.154T>C p.F52L | Missense Mutation (SNP) | VAF 37/480 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- GOLGA2 | c.2006A>T p.Q669L | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GOLGA6D | c.2076C>A p.D692E | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- GPR15 | c.887G>T p.C296F | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GRIK4 | c.2192G>T p.R731L | Missense Mutation (SNP) | VAF 91/154 reads (59%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY1B1 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- HAPLN2 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- HIVEP2 | c.4501G>T p.A1501S | Missense Mutation (SNP) | VAF 124/255 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- HKDC1 | c.1837-1G>T p.X613_splice | Splice Site (SNP) | VAF 41/136 reads (30%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 13/304 reads (4%) | called by muse, mutect2
- HOXD12 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPG2 | c.12098G>C p.R4033P | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HTR2C | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 159/286 reads (56%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IFT122 | c.125A>T p.D42V | Missense Mutation (SNP) | VAF 214/604 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGFN1 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- IGHV3-48 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IGKV1D-43 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by mutect2, varscan2
- IGKV1D-43 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 114/374 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- INTS7 | c.1032A>C p.L344F | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IRX6 | c.440C>A p.A147D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2
- ITIH1 | c.2072A>T p.N691I | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KCNH6 | c.1500C>T p.G500= | Splice Region (SNP) | VAF 14/49 reads (29%) | called by muse, varscan2
- KCNT2 | c.3187T>A p.L1063M | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KIFC3 | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- KRTAP10-8 | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- KRTAP19-8 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- L3MBTL4 | c.298del p.V100Yfs*7 | Frame Shift Del (DEL) | VAF 57/236 reads (24%) | called by mutect2, pindel, varscan2
- LAMA1 | c.2275-1G>T p.X759_splice | Splice Site (SNP) | VAF 63/286 reads (22%) | called by muse, mutect2, varscan2
- LAMA1 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LAMA2 | c.3019C>A p.Q1007K | Missense Mutation (SNP) | VAF 69/346 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- LBX1 | c.504A>T p.Q168H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LEF1 | c.295G>T p.G99* | Nonsense Mutation (SNP) | VAF 39/152 reads (26%) | called by muse, mutect2, varscan2
- LILRA1 | c.121C>G p.Q41E | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, varscan2
- LILRA1 | c.1464C>A p.S488R | Missense Mutation (SNP) | VAF 92/215 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LINC01118 | n.1243+1G>T | Splice Site (SNP) | VAF 69/213 reads (32%) | called by muse, mutect2, varscan2
- LRP3 | c.1519G>T p.V507L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by mutect2, varscan2
- LTN1 | c.1620A>T p.R540S | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MAGED1 | c.1782-1G>T p.X594_splice | Splice Site (SNP) | VAF 60/108 reads (56%) | called by mutect2, varscan2
- MARK3 | c.2179G>T p.G727W (on ENST00000429436 / NM_001128918.3; = p.G703W on NM_002376.6) | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MB | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ME3 | c.1808C>A p.T603K | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MED24 | c.1507G>T p.V503L | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2
- MMP9 | c.2025G>T p.Q675H | Missense Mutation (SNP) | VAF 352/829 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- MMRN1 | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MN1 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- MPO | c.2193T>A p.S731R | Missense Mutation (SNP) | VAF 53/391 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC17 | c.752C>A p.A251D | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); called by mutect2, varscan2
- MYH6 | c.4114C>T p.Q1372* | Nonsense Mutation (SNP) | VAF 93/331 reads (28%) | called by muse, mutect2, varscan2
- MYH8 | c.2074G>T p.V692L | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2
- MYO18B | c.3267G>T p.L1089F | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- MYO18B | c.6453C>A p.S2151R | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO5A | c.2441G>T p.R814I | Missense Mutation (SNP) | VAF 117/458 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, varscan2
- N4BP2L2 | c.717G>T p.L239F | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NBPF12 | c.1460G>C p.G487A | Missense Mutation (SNP) | VAF 145/725 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NDUFA8 | c.54G>T p.V18= | Splice Region (SNP) | VAF 72/334 reads (22%) | called by muse, mutect2, varscan2
- NEB | c.8471C>A p.A2824D | Missense Mutation (SNP) | VAF 108/277 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEFM | c.1793A>T p.K598M | Missense Mutation (SNP) | VAF 118/307 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- NEK1 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NOX4 | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 101/257 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- NPBWR2 | c.751C>A p.L251I | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NPBWR2 | c.646A>T p.T216S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- NUAK1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- OPRD1 | c.1009T>A p.C337S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR10J3 | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 105/391 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- OR1J4 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- OR1L6 | c.1038C>A p.Y346* (on ENST00000373684; = p.Y310* on NM_001004453.2) | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, varscan2
- OR2T27 | c.88del p.L30Sfs*7 | Frame Shift Del (DEL) | VAF 38/224 reads (17%) | called by mutect2, pindel, varscan2
- OR4C5 | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 208/416 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- OR51F1 | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- OR5D13 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2
- OR8H3 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2
- OVCH1 | c.973G>T p.G325* | Nonsense Mutation (SNP) | VAF 52/323 reads (16%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4352G>T p.G1451V | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PAWR | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PCDH7 | c.1636G>C p.E546Q | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDCD1 | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PDLIM2 | c.502G>T p.D168Y (on ENST00000397760; = p.D418Y on NM_021630.6) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PDP2 | c.1215G>T p.K405N | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- PEAR1 | c.1628A>T p.D543V | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PGK2 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 108/295 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHOX2A | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIKFYVE | c.2018del p.G673Efs*23 | Frame Shift Del (DEL) | VAF 74/266 reads (28%) | called by mutect2, pindel*, varscan2
- PKD1L3 | c.2493C>A p.D831E | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLA2G4D | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 53/299 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PLB1 | c.2820G>T p.E940D | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA1 | c.4219G>T p.V1407L | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLXNA4 | c.5295C>A p.S1765R | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPAT | c.995C>G p.A332G | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2
- PPP1R37 | c.1893_1909del p.P632Efs*11 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- PRKG1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRR9 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- PRSS54 | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- PRUNE2 | c.3901G>T p.A1301S | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PSD2 | c.1847G>A p.W616* | Nonsense Mutation (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- PTPN22 | c.1270G>T p.G424* (on ENST00000359785 / NM_001193431.2; = p.G369* on NM_012411.5) | Nonsense Mutation (SNP) | VAF 71/330 reads (22%) | called by muse, mutect2, varscan2
- PTPRT | c.280A>C p.T94P | Missense Mutation (SNP) | VAF 18/295 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2
- PTPRZ1 | c.3827G>T p.S1276I | Missense Mutation (SNP) | VAF 82/205 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PWWP2B | c.757A>T p.I253F | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RAD51AP1 | c.608-1G>C p.X203_splice (on ENST00000228843 / NM_001130862.2; = p.X186_splice on NM_006479.5) | Splice Site (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2
- RAPGEF4 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RBMS3 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- RHBDF1 | c.1126G>T p.V376L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RHBDF2 | c.1820G>T p.S607I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- RHD | c.555G>T p.W185C | Missense Mutation (SNP) | VAF 154/472 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RIT2 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RTL1 | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- RTP1 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- RUBCNL | c.535+1del p.X179_splice | Splice Site (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- RUNX3 | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- RYR2 | c.7672G>T p.G2558C | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR2 | c.10455C>A p.D3485E | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.127); called by muse, varscan2
- SALL1 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SCAPER | c.1371del p.E458Kfs*56 | Frame Shift Del (DEL) | VAF 100/279 reads (36%) | called by mutect2, pindel, varscan2
- SCN5A | c.2950C>T p.L984F | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SEMA3G | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINA12 | c.1046T>A p.V349E | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SESN3 | c.505A>T p.I169F | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); called by muse, varscan2
- SH3RF1 | c.1654_1679del p.P552Ifs*12 | Frame Shift Del (DEL) | VAF 34/313 reads (11%) | called by mutect2, pindel
- SHANK1 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- SHCBP1 | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIGLEC5 | c.1128C>A p.S376R | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- SKOR2 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 66/277 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SLC8A3 | c.727G>C p.V243L | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLCO1C1 | c.934T>C p.S312P | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SMIM2 | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SMIM2 | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- SP100 | c.1353C>A p.S451R | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- SPATA31D1 | c.2041T>A p.S681T | Missense Mutation (SNP) | VAF 133/554 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SPATA5 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPHKAP | c.1912G>C p.D638H | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.024); called by muse, mutect2
- SREBF2 | c.1166A>C p.Q389P | Missense Mutation (SNP) | VAF 123/516 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- STAB1 | c.1126C>A p.L376M | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STK10 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- STON2 | c.333G>C p.W111C | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SV2C | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SYCE1 | c.560C>A p.A187D (on ENST00000343131 / NM_001143764.3; = p.A151D on NM_130784.3) | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- SYNE2 | c.3869A>T p.H1290L | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TAS2R50 | c.688A>G p.T230A | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TBC1D8 | c.387G>T p.R129S | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TDRD15 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- TECRL | c.455C>A p.T152K | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TFB2M | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- THSD1 | c.2018T>A p.L673Q | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR4 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- TMEM132B | c.1422+4A>T | Splice Region (SNP) | VAF 146/356 reads (41%) | called by muse, mutect2, varscan2
- TMEM132C | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 210/480 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM151B | c.468G>C p.M156I | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2
- TMEM71 | c.447G>T p.K149N (on ENST00000523829 / NM_001382398.1; = p.K130N on NM_144649.3) | Missense Mutation (SNP) | VAF 113/193 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TNIP2 | c.1186G>T p.A396S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TNR | c.1427C>A p.P476H | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPH1 | c.1324C>A p.P442T | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.049); called by muse, varscan2
- TPX2 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 50/203 reads (25%) | called by muse, mutect2, varscan2
- TRANK1 | c.2806G>A p.G936S | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM64 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.081); called by mutect2, varscan2
- TRIO | c.6642_6644del p.F2214_K2215delinsL | In Frame Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- TRPV6 | c.270_272del p.L91del | In Frame Del (DEL) | VAF 34/340 reads (10%) | called by mutect2, pindel
- TSNARE1 | c.425A>T p.K142M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TTC27 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- TYSND1 | c.1250A>G p.D417G | Missense Mutation (SNP) | VAF 60/232 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBASH3A | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UBE3D | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- UGT2B28 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 44/132 reads (33%) | called by muse, mutect2, varscan2
- UTP25 | c.895G>C p.A299P | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VSX1 | c.13del p.D5Tfs*99 | Frame Shift Del (DEL) | VAF 108/419 reads (26%) | called by mutect2, pindel, varscan2
- WDR97 | c.1477A>T p.T493S | Missense Mutation (SNP) | VAF 65/98 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- WNK2 | c.4681C>A p.P1561T (on ENST00000297954 / NM_001282394.1; = p.P1524T on NM_006648.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- XRCC5 | c.1290G>T p.L430F | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ZBTB2 | c.1363A>T p.K455* | Nonsense Mutation (SNP) | VAF 93/197 reads (47%) | called by muse, mutect2, varscan2
- ZC2HC1A | c.211-1G>T p.X71_splice | Splice Site (SNP) | VAF 120/174 reads (69%) | called by muse, varscan2
- ZNF331 | c.644A>T p.Y215F | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ZNF724 | c.1450G>T p.G484C | Missense Mutation (SNP) | VAF 79/164 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF862 | c.1401G>C p.R467S | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ACD | c.1095G>T p.P365= (on ENST00000620338; = p.P276= on NM_022914.3) | Silent (SNP) | VAF 85/247 reads (34%) | catalogued as COSV99537813; called by muse, mutect2, varscan2
- ADAD2 | c.741G>C p.P247= (on ENST00000315906 / NM_001145400.2; = p.P329= on NM_139174.4) | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs374108586; called by muse, mutect2, varscan2
- ADGRF4 | c.1536C>A p.S512= | Silent (SNP) | VAF 26/138 reads (19%) | called by muse, varscan2
- ADGRF4 | c.1537C>A p.R513= | Silent (SNP) | VAF 24/136 reads (18%) | called by muse, varscan2
- AEBP1 | c.246C>T p.A82= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs771909045; called by muse, varscan2
- AL136295.3 | c.561G>A p.K187= | Silent (SNP) | VAF 43/96 reads (45%) | called by muse, mutect2, varscan2
- ANK2 | c.4320G>T p.L1440= | Silent (SNP) | VAF 60/444 reads (14%) | called by muse, varscan2
- ARNT2 | c.798C>T p.G266= | Silent (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2
- ATRNL1 | c.1305T>A p.S435= | Silent (SNP) | VAF 51/157 reads (32%) | called by muse, mutect2, varscan2
- C12orf66 | c.957C>T p.N319= | Silent (SNP) | VAF 41/245 reads (17%) | called by muse, mutect2, varscan2
- C19orf81 | c.114G>C p.R38= | Silent (SNP) | VAF 35/250 reads (14%) | called by muse, mutect2, varscan2
- C1QL1 | c.225C>T p.T75= | Silent (SNP) | VAF 15/21 reads (71%) | called by muse, mutect2, varscan2
- C1orf167 | c.1161C>T p.G387= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- C6orf15 | c.63C>A p.L21= | Silent (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- CCDC39 | c.1629A>G p.S543= | Silent (SNP) | VAF 55/228 reads (24%) | called by muse, mutect2, varscan2
- CCDC83 | c.255G>A p.E85= | Silent (SNP) | VAF 100/219 reads (46%) | catalogued as rs1452997273, COSV99721491; called by muse, mutect2, varscan2
- CDH7 | c.1800C>A p.V600= | Silent (SNP) | VAF 58/275 reads (21%) | called by muse, varscan2
- CGB2 | c.393C>A p.P131= | Silent (SNP) | VAF 46/217 reads (21%) | called by muse, mutect2, varscan2
- CHSY3 | c.1338G>T p.L446= | Silent (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- CLDN17 | c.297C>T p.I99= | Silent (SNP) | VAF 12/149 reads (8%) | catalogued as COSV54522681; called by muse, mutect2
- CNGB3 | c.378G>A p.E126= | Silent (SNP) | VAF 119/1013 reads (12%) | called by muse, mutect2, varscan2
- COL26A1 | c.402C>A p.T134= (on ENST00000313669 / NM_001278563.3; = p.T132= on NM_133457.4) | Silent (SNP) | VAF 45/148 reads (30%) | catalogued as COSV58122431; called by muse, mutect2, varscan2
- CTNNA2 | c.762C>A p.I254= | Silent (SNP) | VAF 131/361 reads (36%) | catalogued as rs1004199042, COSV63547299; called by muse, mutect2, varscan2
- CTNND2 | c.2586G>T p.T862= | Silent (SNP) | VAF 107/216 reads (50%) | catalogued as COSV58903550; called by muse, mutect2, varscan2
- DDX11 | c.120G>T p.G40= | Silent (SNP) | VAF 25/374 reads (7%) | catalogued as rs1390080169, COSV99300086; called by muse, varscan2
- DNAH6 | c.6690C>T p.F2230= | Silent (SNP) | VAF 104/375 reads (28%) | catalogued as rs376746872; called by muse, mutect2, varscan2
- DUSP2 | c.456G>A p.P152= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV56620657; called by muse, mutect2, varscan2
- EDARADD | c.441G>T p.G147= (on ENST00000334232 / NM_145861.4; = p.G137= on NM_080738.4) | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV100513138; called by muse, mutect2, varscan2
- EIF4E | c.186G>C p.L62= | Silent (SNP) | VAF 69/330 reads (21%) | called by muse, mutect2, varscan2
- ELFN1 | c.1560C>T p.A520= | Silent (SNP) | VAF 35/53 reads (66%) | catalogued as COSV70036733; called by muse, mutect2, varscan2
- EXD3 | c.174G>T p.G58= | Silent (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- EYS | c.2352C>A p.S784= | Silent (SNP) | VAF 73/164 reads (45%) | catalogued as COSV65494625; called by muse, mutect2, varscan2
- FAM135B | c.4107C>A p.A1369= | Silent (SNP) | VAF 98/1048 reads (9%) | called by muse, mutect2
- FAM149A | c.684C>T p.S228= | Silent (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2, varscan2
- FERMT2 | c.312C>A p.P104= | Silent (SNP) | VAF 21/712 reads (3%) | called by muse, mutect2
- FRYL | c.1056T>C p.S352= | Silent (SNP) | VAF 52/158 reads (33%) | called by muse, mutect2, varscan2
- FTMT | c.18G>A p.R6= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs1301227334; called by muse, mutect2, varscan2
- GIGYF1 | c.2622G>T p.S874= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs771298452; called by muse, mutect2, varscan2
- HDGF | c.273C>T p.N91= | Silent (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- HLA-DRB1 | c.486G>A p.L162= | Silent (SNP) | VAF 97/820 reads (12%) | catalogued as rs746709087, COSV63521841; called by muse, varscan2
- IGFBP5 | c.474G>A p.K158= | Silent (SNP) | VAF 89/215 reads (41%) | called by muse, mutect2, varscan2
- IGSF10 | c.1785C>T p.C595= | Silent (SNP) | VAF 20/224 reads (9%) | catalogued as rs375970433; called by muse, mutect2
- IL21R | c.1551G>T p.R517= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as COSV61971350; called by muse, mutect2, varscan2
- INSM2 | c.480G>A p.P160= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs1270937218; called by muse, mutect2, varscan2
- KCND2 | c.424C>A p.R142= | Silent (SNP) | VAF 36/153 reads (24%) | catalogued as rs1387288913, COSV58571832; called by muse, mutect2, varscan2
- KIF7 | c.1767T>A p.V589= | Silent (SNP) | VAF 149/324 reads (46%) | called by muse, mutect2, varscan2
- KRT4 | c.1200G>A p.K400= | Silent (SNP) | VAF 54/263 reads (21%) | catalogued as rs1288825566; called by muse, mutect2, varscan2
- KRTAP10-5 | c.21C>T p.S7= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs1285941923; called by muse, mutect2, varscan2
- LGR5 | c.1680C>A p.I560= | Silent (SNP) | VAF 42/84 reads (50%) | called by muse, mutect2, varscan2
- LRP1 | c.7626G>C p.L2542= | Silent (SNP) | VAF 70/213 reads (33%) | called by muse, mutect2, varscan2
- MAP1B | c.1443G>A p.A481= | Silent (SNP) | VAF 53/180 reads (29%) | catalogued as rs533759374, COSV57106226; called by muse, mutect2, varscan2
- MC2R | c.681C>A p.V227= | Silent (SNP) | VAF 96/306 reads (31%) | called by muse, mutect2, varscan2
- MGAM2 | c.4197C>A p.P1399= | Silent (SNP) | VAF 64/135 reads (47%) | called by muse, mutect2, varscan2
- MIDEAS | c.2055C>T p.P685= | Silent (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- MTHFD1L | c.1452C>T p.H484= | Silent (SNP) | VAF 78/146 reads (53%) | catalogued as rs1466639287, COSV66226343; called by muse, mutect2, varscan2
- MYH6 | c.2388C>A p.G796= | Silent (SNP) | VAF 151/385 reads (39%) | called by muse, mutect2, varscan2
- MYO16 | c.2667G>T p.G889= | Silent (SNP) | VAF 66/310 reads (21%) | catalogued as COSV51778856; called by muse, mutect2, varscan2
- MYO16 | c.5286G>T p.R1762= | Silent (SNP) | VAF 44/174 reads (25%) | catalogued as COSV62751051; called by muse, varscan2
- MYOM2 | c.528C>A p.T176= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as rs139319077; called by muse, mutect2, varscan2
- NAV3 | c.1743C>A p.A581= | Silent (SNP) | VAF 74/157 reads (47%) | catalogued as rs758893961; called by muse, mutect2, varscan2
- NCKAP5 | c.4197C>T p.A1399= | Silent (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- NKD2 | c.156G>A p.G52= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as rs778242161; called by muse, mutect2, varscan2
- NPY5R | c.705C>T p.C235= | Silent (SNP) | VAF 64/171 reads (37%) | called by muse, mutect2, varscan2
- NYX | c.57C>A p.P19= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- OTOG | c.5931C>A p.A1977= | Silent (SNP) | VAF 77/180 reads (43%) | called by muse, mutect2, varscan2
- PAPPA | c.906T>C p.D302= | Silent (SNP) | VAF 71/242 reads (29%) | catalogued as rs1178275227; called by muse, mutect2, varscan2
- PARVG | c.207G>A p.E69= | Silent (SNP) | VAF 61/245 reads (25%) | catalogued as COSV100796070; called by muse, mutect2, varscan2
- PC | c.354C>T p.Y118= | Silent (SNP) | VAF 148/268 reads (55%) | catalogued as rs756061375, COSV63081801; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDH17 | c.636G>A p.V212= | Silent (SNP) | VAF 28/166 reads (17%) | called by muse, mutect2, varscan2
- PCDHA8 | c.1869C>T p.R623= | Silent (SNP) | VAF 48/164 reads (29%) | catalogued as COSV100969367; called by muse, mutect2, varscan2
- PCDHGA4 | c.657G>T p.G219= | Silent (SNP) | VAF 70/192 reads (36%) | called by muse, mutect2, varscan2
- PM20D1 | c.928C>T p.L310= | Silent (SNP) | VAF 18/268 reads (7%) | catalogued as COSV65649091; called by muse, mutect2
- PRAMEF2 | c.1323G>T p.L441= | Silent (SNP) | VAF 4/17 reads (24%) | called by mutect2, varscan2
- PSD3 | c.2394A>T p.A798= (on ENST00000440756; = p.A797= on NM_015310.4) | Silent (SNP) | VAF 32/254 reads (13%) | called by muse, mutect2, varscan2
- RAB3IL1 | c.600C>T p.C200= | Silent (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- RASSF2 | c.732C>A p.A244= | Silent (SNP) | VAF 67/262 reads (26%) | called by muse, mutect2, varscan2
- RNF122 | c.234G>T p.V78= | Silent (SNP) | VAF 68/241 reads (28%) | called by muse, mutect2, varscan2
- ROR1 | c.2658A>T p.P886= | Silent (SNP) | VAF 76/229 reads (33%) | called by muse, mutect2, varscan2
- RXFP4 | c.1005C>A p.G335= | Silent (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- RYR2 | c.6405C>G p.G2135= | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- SAMSN1 | c.450C>A p.T150= | Silent (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- SCN5A | c.4885C>A p.R1629= (on ENST00000333535 / NM_198056.3; = p.R1628= on NM_000335.5) | Silent (SNP) | VAF 67/182 reads (37%) | catalogued as CM099835, CM100747; called by muse, mutect2, varscan2
- SEMA3F | c.1677C>T p.C559= | Silent (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- SH2D4B | c.288T>C p.S96= | Silent (SNP) | VAF 71/246 reads (29%) | catalogued as COSV57894570; called by muse, mutect2, varscan2
- SH3RF1 | c.150C>A p.P50= | Silent (SNP) | VAF 12/185 reads (6%) | catalogued as COSV99498501; called by muse, mutect2
- SIGLEC9 | c.72G>A p.T24= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs373690399; called by muse, varscan2
- SLC17A2 | c.18C>A p.A6= | Silent (SNP) | VAF 98/340 reads (29%) | called by muse, mutect2, varscan2
- SLC35G5 | c.954C>A p.G318= | Silent (SNP) | VAF 18/336 reads (5%) | catalogued as COSV55310975; called by muse, mutect2
- SLC6A2 | c.198G>T p.L66= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as rs1349748778; called by muse, mutect2, varscan2
- SRF | c.1416A>T p.A472= | Silent (SNP) | VAF 99/344 reads (29%) | called by muse, mutect2, varscan2
- TAS2R60 | c.807T>A p.G269= | Silent (SNP) | VAF 143/306 reads (47%) | called by muse, mutect2, varscan2
- TCF21 | c.186G>T p.A62= | Silent (SNP) | VAF 87/161 reads (54%) | catalogued as COSV52817951; called by muse, mutect2, varscan2
- TEPP | c.438C>A p.P146= | Silent (SNP) | VAF 83/279 reads (30%) | called by muse, mutect2, varscan2
- TG | c.5055C>A p.T1685= | Silent (SNP) | VAF 306/598 reads (51%) | called by muse, mutect2, varscan2
- TLN2 | c.5163G>T p.A1721= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV60890957; called by muse, mutect2, varscan2
- TMEM104 | c.339G>T p.L113= | Silent (SNP) | VAF 44/141 reads (31%) | called by muse, mutect2, varscan2
- TMEM127 | c.111C>T p.G37= | Silent (SNP) | VAF 75/208 reads (36%) | called by muse, mutect2, varscan2
- TP53BP1 | c.3288C>A p.V1096= | Silent (SNP) | VAF 50/179 reads (28%) | called by muse, mutect2, varscan2
- TTBK2 | c.3564C>T p.S1188= | Silent (SNP) | VAF 94/251 reads (37%) | called by muse, mutect2, varscan2
- TTC34 | c.1692C>T p.A564= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- TYR | c.192A>T p.P64= | Silent (SNP) | VAF 166/585 reads (28%) | catalogued as COSV54478728; called by muse, mutect2, varscan2
- UBAC2 | c.102G>T p.L34= (on ENST00000403766 / NM_001144072.2; = p.C76F on NM_177967.4) | Silent (SNP) | VAF 58/199 reads (29%) | called by muse, mutect2, varscan2
- UNC13B | c.1713C>T p.D571= | Silent (SNP) | VAF 16/414 reads (4%) | called by muse, mutect2
- USH2A | c.11403C>A p.P3801= | Silent (SNP) | VAF 60/204 reads (29%) | called by muse, varscan2
- VCX3A | c.42C>A p.A14= | Silent (SNP) | VAF 55/241 reads (23%) | called by muse, varscan2
- VSTM1 | c.348G>T p.V116= | Silent (SNP) | VAF 19/102 reads (19%) | called by muse, varscan2
- WDR64 | c.2910C>A p.P970= | Silent (SNP) | VAF 52/179 reads (29%) | called by muse, mutect2, varscan2
- WIPI2 | c.1035G>A p.L345= | Silent (SNP) | VAF 149/247 reads (60%) | called by muse, mutect2, varscan2
- WSCD1 | c.1461G>T p.V487= | Silent (SNP) | VAF 129/191 reads (68%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.1524C>A p.R508= | Silent (SNP) | VAF 68/142 reads (48%) | called by muse, mutect2, varscan2
- YIPF5 | c.195G>A p.Q65= | Silent (SNP) | VAF 13/412 reads (3%) | called by muse, mutect2
- ZMYM6 | c.126A>G p.Q42= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as rs1242859384; called by muse, mutect2, varscan2
- ZNF521 | c.2196C>T p.D732= | Silent (SNP) | VAF 88/246 reads (36%) | catalogued as COSV64123804; called by mutect2, varscan2
- AC021218.1 | n.1066G>T | RNA (SNP) | VAF 4/11 reads (36%) | called by muse, varscan2
- AC026410.1 | n.701C>A | RNA (SNP) | VAF 43/147 reads (29%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-9361C>A | Intron (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- ADAM22 | c.86-120_86-111del | Intron (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- AGAP12P | n.1782C>A | RNA (SNP) | VAF 36/529 reads (7%) | called by muse, mutect2
- AL353804.7 | chrX:73845864 C>T | 5'Flank (SNP) | VAF 80/197 reads (41%) | catalogued as rs1195185692; called by muse, mutect2, varscan2
- ANKDD1A | c.1483+1004C>T | Intron (SNP) | VAF 13/68 reads (19%) | catalogued as rs201902905; called by muse, mutect2, varscan2
- ANKRD26P1 | n.1505C>T | RNA (SNP) | VAF 87/326 reads (27%) | catalogued as rs1407497298; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504192 C>T | 5'Flank (SNP) | VAF 10/219 reads (5%) | called by muse, mutect2
- AP000769.5 | chr11:65500770 A>C | 5'Flank (SNP) | VAF 58/440 reads (13%) | called by muse, mutect2, varscan2
- ARPC1A | c.169+1669C>T | Intron (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- AXIN1 | c.2294+21C>A | Intron (SNP) | VAF 72/171 reads (42%) | called by muse, mutect2, varscan2
- BNIP1 | c.490+785G>C | Intron (SNP) | VAF 46/186 reads (25%) | called by muse, mutect2, varscan2
- C1orf109 | c.-4+16G>T | Intron (SNP) | VAF 34/155 reads (22%) | called by muse, mutect2, varscan2
- CAMK2A | c.1033+108C>G | Intron (SNP) | VAF 62/264 reads (23%) | called by muse, mutect2, varscan2
- CEP170P1 | n.3810A>G | RNA (SNP) | VAF 33/159 reads (21%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2973G>T | 3'UTR (SNP) | VAF 26/88 reads (30%) | called by muse, mutect2, varscan2
- CLCN5 | c.17-38743dup | Intron (INS) | VAF 33/80 reads (41%) | called by mutect2, pindel, varscan2
- CYP2A7P1 | n.270G>A | RNA (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- DIP2C | c.157+1648G>T | Intron (SNP) | VAF 11/204 reads (5%) | called by muse, mutect2
- DIP2C | c.85+39233C>T | Intron (SNP) | VAF 20/133 reads (15%) | catalogued as rs756636493; called by muse, mutect2, varscan2
- DZANK1 | c.379-127A>T | Intron (SNP) | VAF 110/298 reads (37%) | called by muse, mutect2, varscan2
- EBF3 | c.1759+1115G>A | Intron (SNP) | VAF 49/213 reads (23%) | called by muse, mutect2, varscan2
- ENPP2 | c.973-2084C>A | Intron (SNP) | VAF 177/338 reads (52%) | catalogued as COSV99308982; called by muse, mutect2, varscan2
- FAM167A | c.381+5555G>T | Intron (SNP) | VAF 57/193 reads (30%) | catalogued as rs1325969050; called by muse, mutect2, varscan2
- FAM74A3 | n.152C>A | RNA (SNP) | VAF 81/349 reads (23%) | called by muse, mutect2, varscan2
- FAM74A7 | n.658C>A | RNA (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2, varscan2
- GFRA2 | c.41-134C>A | Intron (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2
- GLYATL1 | c.-166-277G>C | Intron (SNP) | VAF 36/61 reads (59%) | called by muse, mutect2, varscan2
- GOLGA8IP | chr15:22617759 C>A | 5'Flank (SNP) | VAF 16/82 reads (20%) | called by mutect2, varscan2
- HECW1 | c.-116C>A | 5'UTR (SNP) | VAF 91/278 reads (33%) | called by muse, mutect2, varscan2
- HSPH1 | c.-68G>T | 5'UTR (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-3572C>A | Intron (SNP) | VAF 146/484 reads (30%) | called by muse, varscan2
- LINC00602 | n.831C>G | RNA (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- LINC00955 | n.844C>A | RNA (SNP) | VAF 26/119 reads (22%) | called by muse, mutect2, varscan2
- LITAF | c.*1395G>T | 3'UTR (SNP) | VAF 58/191 reads (30%) | catalogued as rs1354815434; called by muse, mutect2, varscan2
- MAG | c.1716+270G>A | Intron (SNP) | VAF 34/209 reads (16%) | catalogued as rs144359826, COSV62699746; called by muse, mutect2, varscan2
- MAGI1 | c.2417-3523C>T | Intron (SNP) | VAF 64/243 reads (26%) | called by muse, varscan2
- MAP1B | c.511-575G>T | Intron (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- MAP3K19 | c.22+1111G>C | Intron (SNP) | VAF 15/342 reads (4%) | catalogued as COSV100209434; called by muse, mutect2
- MAPRE3 | c.267+98C>A | Intron (SNP) | VAF 18/59 reads (31%) | called by muse, varscan2
- MASP1 | c.1303+5109G>A | Intron (SNP) | VAF 42/134 reads (31%) | catalogued as rs376991602; called by muse, mutect2, varscan2
- MAZ | c.1043+36G>A | Intron (SNP) | VAF 18/49 reads (37%) | catalogued as rs1184438471; called by muse, mutect2, varscan2
- MCF2L | c.368+2271T>C | Intron (SNP) | VAF 40/241 reads (17%) | catalogued as rs149645765; called by muse, mutect2, varscan2
- MGAM | c.4619-11277C>T | Intron (SNP) | VAF 93/136 reads (68%) | called by muse, varscan2
- MMAB | c.*1611C>G | 3'UTR (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- MTNR1B | chr11:92984808 del T | 3'Flank (DEL) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- MTNR1B | chr11:92984809 T>A | 3'Flank (SNP) | VAF 16/58 reads (28%) | called by mutect2, varscan2
- NDUFAF5 | c.*844G>C | 3'UTR (SNP) | VAF 184/521 reads (35%) | called by muse, mutect2, varscan2
- NR0B1 | c.*24A>T | 3'UTR (SNP) | VAF 10/264 reads (4%) | called by muse, mutect2
- NTRK1 | c.1196-43A>T | Intron (SNP) | VAF 61/342 reads (18%) | called by muse, mutect2, varscan2
- OR52A4P | n.911C>A | RNA (SNP) | VAF 43/121 reads (36%) | called by muse, mutect2, varscan2
- P2RX1 | c.-4C>A | 5'UTR (SNP) | VAF 37/69 reads (54%) | called by muse, mutect2, varscan2
- PLCG2 | c.*1G>T | 3'UTR (SNP) | VAF 79/242 reads (33%) | called by muse, mutect2, varscan2
- PTPRC | c.3331-29G>T | Intron (SNP) | VAF 55/172 reads (32%) | called by muse, mutect2, varscan2
- RAB18 | c.*1959C>T | 3'UTR (SNP) | VAF 95/229 reads (41%) | catalogued as rs1039817331; called by muse, mutect2, varscan2
- RBM4B | c.*68G>A | 3'UTR (SNP) | VAF 119/210 reads (57%) | called by muse, mutect2, varscan2
- RFX7 | c.-23G>T | 5'UTR (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- RFX7 | c.-24G>T | 5'UTR (SNP) | VAF 28/113 reads (25%) | called by muse, mutect2, varscan2
- RHBG | c.1112+49C>A | Intron (SNP) | VAF 77/161 reads (48%) | catalogued as rs1426984541; called by muse, mutect2, varscan2
- RIMS2 | c.1692+215G>T | Intron (SNP) | VAF 85/610 reads (14%) | catalogued as COSV99157164; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1421C>G | RNA (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- ROR1 | c.-59G>A | 5'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- RPS17 | c.*182G>T | 3'UTR (SNP) | VAF 89/359 reads (25%) | called by muse, mutect2, varscan2
- SH2B3 | c.733-11743_733-11742dup | Intron (INS) | VAF 12/111 reads (11%) | called by mutect2, pindel
- SLC16A10 | c.942+796G>T | Intron (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- SLC24A2 | c.*4G>A | 3'UTR (SNP) | VAF 95/351 reads (27%) | called by muse, mutect2, varscan2
- SLC35A4 | c.*17C>T | 3'UTR (SNP) | VAF 37/124 reads (30%) | called by muse, mutect2, varscan2
- SRGAP3 | c.68-24G>T | Intron (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.6412T>A | RNA (SNP) | VAF 44/147 reads (30%) | called by muse, mutect2, varscan2
- SSPOP | n.7787G>T | RNA (SNP) | VAF 20/79 reads (25%) | catalogued as COSV65133847; called by muse, mutect2, varscan2
- SSX9P | n.233G>T | RNA (SNP) | VAF 48/204 reads (24%) | called by muse, mutect2, varscan2
- TBX15 | c.1025-5412G>T | Intron (SNP) | VAF 23/147 reads (16%) | called by muse, varscan2
- TBX15 | c.1025-5449C>T | Intron (SNP) | VAF 29/96 reads (30%) | catalogued as rs922191657; called by muse, varscan2
- TDP1 | c.1644+3614G>T | Intron (SNP) | VAF 42/218 reads (19%) | called by muse, mutect2, varscan2
- THEM5 | c.*152C>T | 3'UTR (SNP) | VAF 40/155 reads (26%) | catalogued as rs1490587289; called by muse, varscan2
- USH1C | c.1284+6895C>A | Intron (SNP) | VAF 81/464 reads (17%) | called by muse, mutect2, varscan2
- WDR11 | c.-47G>C | 5'UTR (SNP) | VAF 37/145 reads (26%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4876A>T | Intron (SNP) | VAF 115/316 reads (36%) | called by muse, mutect2, varscan2
- ZNF28 | c.142+33G>C | Intron (SNP) | VAF 92/188 reads (49%) | called by muse, mutect2, varscan2
